Somatic mutation profile of tumor specimen C3N-00314-01 (aliquot CPT0012050009) from CPTAC case C3N-00314, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.0 years (28,865 days).
Specimen C3N-00314-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 999136ad-e116-403f-a363-c0bb6e148adf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00314-31 (Blood Derived Normal), aliquot CPT0012150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d551ca6e-d492-4383-912f-66b98942d258

The open-access MAF lists 97 somatic variants for this specimen: 61 protein-altering or splice-affecting, 22 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 22, Intron 8, Frame Shift Del 7, Splice Region 3, 3'UTR 2, Nonsense Mutation 2, 3'Flank 2, Splice Site 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3712G>A p.G1238S | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs200733032; called by muse, mutect2, varscan2
- AKAP13 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs779331144, COSV63466066; called by muse, mutect2, varscan2
- AP3B1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 66/634 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV54877011; called by muse, mutect2, varscan2
- BEST1 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 38/1034 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as CM067981; called by muse, mutect2
- CACNA1C | c.3912+1G>A p.X1304_splice | Splice Site (SNP) | VAF 22/166 reads (13%) | catalogued as rs1247088024; called by muse, mutect2, varscan2
- CARD10 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.194); catalogued as rs769750011, COSV99325255; called by muse, mutect2
- CNTNAP4 | c.2935C>G p.P979A | Missense Mutation (SNP) | VAF 22/664 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as COSV56700287; called by muse, mutect2
- CSMD3 | c.4069C>G p.P1357A (on ENST00000297405 / NM_001363185.1; = p.P1253A on NM_052900.3) | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52108152; called by muse, mutect2
- DISP1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as rs908032421, COSV99450110; called by muse, mutect2, varscan2
- DNAH5 | c.13084G>T p.D4362Y | Missense Mutation (SNP) | VAF 91/613 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54234974; called by muse, mutect2, varscan2
- DPP6 | c.1988G>A p.R663H (on ENST00000377770 / NM_001364500.2; = p.R601H on NM_001936.5) | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs1441382918, COSV59643903; called by muse, mutect2
- HIVEP2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 22/417 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775033088, COSV50012224; called by muse, mutect2
- LILRA4 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52494279; called by muse, mutect2
- MALRD1 | c.5439G>T p.W1813C | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV65978183; called by muse, mutect2
- PDCL3 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 70/868 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748802211; called by muse, mutect2
- SYNJ2 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745840620; called by muse, mutect2, varscan2
- TMEM163 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323094328; called by muse, mutect2, varscan2
- ZNF207 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 72/590 reads (12%) | catalogued as COSV58301642; called by muse, mutect2, varscan2
- ZNF419 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1397210318; called by muse, mutect2, varscan2
- ABCC5 | c.1832A>G p.Q611R | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACBD5 | c.794A>C p.E265A (on ENST00000375888 / NM_001352568.1; = p.E256A on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/733 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2
- ACTN3 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2
- AKAP11 | c.2480A>T p.E827V | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ANKRD42 | c.1058C>G p.T353S | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- BMP5 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC9 | c.246del p.T83Pfs*85 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- CEACAM1 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 44/644 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2
- CHAT | c.1980G>T p.V660= | Splice Region (SNP) | VAF 50/592 reads (8%) | called by muse, mutect2
- CNRIP1 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 12/375 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2
- COL6A5 | c.4669G>T p.E1557* | Nonsense Mutation (SNP) | VAF 48/304 reads (16%) | called by muse, mutect2, varscan2
- CRIM1 | c.2788C>T p.H930Y | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMT1 | c.79C>A p.R27= | Splice Region (SNP) | VAF 57/526 reads (11%) | called by muse, mutect2, varscan2
- DPPA2 | c.329G>C p.S110T | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DUXB | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 32/357 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ESPL1 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 77/463 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GASK1B | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 65/591 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GEMIN5 | c.417del p.F139Lfs*11 | Frame Shift Del (DEL) | VAF 47/424 reads (11%) | called by mutect2, pindel, varscan2
- GTF3C5 | c.801T>G p.N267K | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- HRNR | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 138/1520 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- IGSF10 | c.6162del p.D2055Ifs*4 | Frame Shift Del (DEL) | VAF 47/397 reads (12%) | called by mutect2, pindel, varscan2
- ITIH6 | c.3354del p.L1119Cfs*3 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- KCNG1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- KLRG2 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIF | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MECOM | c.1426G>T p.A476S (on ENST00000468789 / NM_001105078.4; = p.A664S on NM_004991.4) | Missense Mutation (SNP) | VAF 70/473 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NUTM1 | c.1600del p.R534Efs*11 | Frame Shift Del (DEL) | VAF 22/199 reads (11%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2818del p.L940Sfs*74 (on ENST00000296302 / NM_001366071.2; = p.L940Sfs*68 on NM_018313.5) | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | called by mutect2, pindel, varscan2
- PCNT | c.8040G>T p.E2680D | Missense Mutation (SNP) | VAF 70/736 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- PIKFYVE | c.5074C>A p.Q1692K | Missense Mutation (SNP) | VAF 56/614 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2
- RCC1 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RGMB | c.4G>T p.G2C (on ENST00000513185 / NM_001366508.1; = p.G43C on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/881 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- SCO1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 86/829 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SDAD1 | c.196-5T>A | Splice Region (SNP) | VAF 19/295 reads (6%) | called by muse, mutect2
- SLTM | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SMG1 | c.7465G>A p.D2489N | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TOE1 | c.295T>A p.S99T | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TSPY1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 186/3568 reads (5%) | called by muse, mutect2
- ZBTB16 | c.1037T>G p.L346W | Missense Mutation (SNP) | VAF 73/736 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZCCHC7 | c.556_563del p.K186* | Frame Shift Del (DEL) | VAF 21/308 reads (7%) | called by muse*, mutect2
- ZMYM4 | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF512B | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 40/497 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AK3 | c.457C>T p.L153= | Silent (SNP) | VAF 20/337 reads (6%) | called by muse, mutect2
- BPIFB3 | c.840G>A p.V280= | Silent (SNP) | VAF 39/479 reads (8%) | called by muse, mutect2
- CAPN1 | c.315A>T p.T105= | Silent (SNP) | VAF 33/403 reads (8%) | called by muse, mutect2
- DOK2 | c.1116G>T p.A372= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- ESYT3 | c.309C>T p.G103= | Silent (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- EXT2 | c.657G>A p.T219= (on ENST00000343631; = p.T252= on NM_000401.3) | Silent (SNP) | VAF 59/1163 reads (5%) | catalogued as rs368087959, COSV59155038; called by muse, mutect2
- HIP1 | c.309C>G p.L103= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.231T>C p.H77= | Silent (SNP) | VAF 58/571 reads (10%) | catalogued as rs1170472411, COSV51533984; called by muse, mutect2
- KCNG1 | c.1182G>C p.L394= | Silent (SNP) | VAF 17/352 reads (5%) | catalogued as COSV65369535; called by muse, mutect2
- KMT2C | c.8979C>T p.L2993= | Silent (SNP) | VAF 38/526 reads (7%) | catalogued as COSV51439610; called by muse, mutect2
- NEUROD2 | c.1071T>C p.N357= | Silent (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- NVL | c.234A>G p.L78= | Silent (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- PHF3 | c.1857A>T p.V619= | Silent (SNP) | VAF 15/227 reads (7%) | called by muse, mutect2
- PLXNA4 | c.4473C>T p.I1491= | Silent (SNP) | VAF 55/551 reads (10%) | called by muse, mutect2
- PRSS27 | c.444C>T p.P148= | Silent (SNP) | VAF 29/242 reads (12%) | catalogued as rs915952005; called by muse, mutect2, varscan2
- PTX4 | c.501G>A p.R167= (on ENST00000447419 / NM_001328608.2; = p.R162= on NM_001013658.1) | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV99560379; called by muse, mutect2, varscan2
- SERPINB6 | c.1179C>G p.S393= (on ENST00000612421 / NM_001271823.2; = p.S374= on NM_004568.6) | Silent (SNP) | VAF 46/533 reads (9%) | catalogued as rs768602128; called by muse, mutect2
- SH3GLB1 | c.1053C>T p.N351= | Silent (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- TMEM151B | c.882C>A p.P294= | Silent (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- ZFR2 | c.1173G>A p.A391= | Silent (SNP) | VAF 23/255 reads (9%) | catalogued as rs963844831, COSV53596101; called by muse, mutect2
- ZMYND8 | c.2904G>A p.E968= (on ENST00000311275 / NM_001363741.2; = p.E942= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/465 reads (8%) | catalogued as COSV53696825; called by muse, mutect2
- ZNF516 | c.12C>T p.N4= | Silent (SNP) | VAF 31/439 reads (7%) | catalogued as rs754764602; called by muse, mutect2
- AC116366.2 | c.-659_-655del | 5'UTR (DEL) | VAF 46/403 reads (11%) | called by mutect2, pindel
- ALOXE3 | chr17:8118767 C>T | 5'Flank (SNP) | VAF 18/480 reads (4%) | catalogued as rs1298426740; called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39434C>T | Intron (SNP) | VAF 58/778 reads (7%) | called by muse, mutect2
- CACNB4 | c.390+55T>G | Intron (SNP) | VAF 32/406 reads (8%) | called by muse, mutect2
- CD8A | c.*612A>G | 3'UTR (SNP) | VAF 18/384 reads (5%) | catalogued as rs1408619421; called by muse, mutect2
- NME5 | c.129+27dup | Intron (INS) | VAF 37/335 reads (11%) | called by mutect2, pindel, varscan2
- PHF20 | c.1826-137del | Intron (DEL) | VAF 48/430 reads (11%) | called by mutect2, pindel, varscan2
- POMT2 | c.1725+16G>T | Intron (SNP) | VAF 71/690 reads (10%) | called by muse, mutect2, varscan2
- RMDN1 | chr8:86468706 del C | 3'Flank (DEL) | VAF 22/226 reads (10%) | called by mutect2, pindel
- RN7SL484P | chr15:99792697 G>A | 3'Flank (SNP) | VAF 20/376 reads (5%) | catalogued as rs1407716729; called by muse, mutect2
- SLC27A4 | c.-6-857C>T | Intron (SNP) | VAF 22/458 reads (5%) | catalogued as rs551080094, COSV55960798, COSV55960909; called by muse, mutect2
- TMEM179 | c.*2066G>A | 3'UTR (SNP) | VAF 18/602 reads (3%) | catalogued as rs774994412; called by muse, mutect2
- ZNF528 | c.272-836C>G | Intron (SNP) | VAF 42/443 reads (9%) | catalogued as rs761426106; called by muse, mutect2
- ZNF829 | c.-85+146A>C | Intron (SNP) | VAF 42/447 reads (9%) | called by muse, mutect2, varscan2
